Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-7051, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-7051-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

with right renal mass.

Specimens Submitted:

- 1: KIDNEY, RIGHT, PARTIAL NEPHRECTOMY
- 2: LYMPH NODES, PRECAVAL AND PARACAVAL, EXCISION
- 3: RIGHT ADRENAL GLAND AND SUPRAHILAR LYMPH NODE, EXCISION

DIAGNOSIS:

1. KIDNEY, RIGHT, PARTIAL NEPHRECTOMY

Tumor Type:

Renal cell carcinoma - Papillary type

Low grade

Tumor Size:

Greatest diameter is 17 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

See part 3

Lymph Nodes:

See part 2

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

Comment: The immunohistochemical stains show that the renal cell carcinoma, papillary type is positive for CK7, racemase, focally positive for CA-9 and negative for CD10 supporting the diagnosis.

2. LYMPH NODES, PRECAVAL AND PARACAVAL, EXCISION

Lymph Nodes:

Not involved

[page 2 of 3]
Number of nodes examined:5

3. RIGHT ADRENAL GLAND AND SUPRAHILAR LYMPH NODE, EXCISION:
Benign adrenal gland

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	CK7	
	RACEMASE	
	CD10	
	VIMEN	
	NEG CONT	
	IMM RECUT	

Gross Description:

1). The specimen is received fresh labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 2 g in total. The kidney measures 22 x 15 x 11 cm. The attached ureter measures 2.5 cm in length and 0.3 cm in diameter. The attached renal vein measures 1.3 cm in length and 1.1 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a large cystic tumor measuring 17 x 11 x 8 cm, involving the upper pole of the cortex and is filled with dark brown necrotic fluid, and yellow-brown, necrotic tissue. The tumor is 5 cm from the ureter margin. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 0.7 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. The specimen is photographed. Representative sections are submitted

Summary of sections:

UVM -- ureteral and vessel margins

T-- tumor

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

2). The specimen is received in formalin, labeled "precaval and paracaval lymph nodes " and consists of multiple pink tan firm lymph nodes ranging from 1 to 2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

3). The specimen is received in formalin, labeled "right adrenal gland and suprahilar lymph node" and consists of an irregular shaped fragment of yellow lobulated adipose tissue measuring 5.5 x 4 x 2.5 cm. Sectioning shows a yellow-tan adrenal gland measuring 4.5 x 1.7 x 1 cm and weighing 7 g. Sectioning shows unremarkable cortex and medulla. Grossly no lymph node is identified.

Summary of sections:
U-undesignated.

Summary of Sections:

Part 1: KIDNEY, RIGHT, PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
2	k	2
2	rp	2
4	l	4
2	tk	2
3	tsf	3
1	uvm	1

Part 2: LYMPH NODES, PRECAVAL AND PARACAVAL, EXCISION

Block	Sect. Site	PCs
2	ln	2

Part 3: RIGHT ADRENAL GLAND AND SUPRAHILAR LYMPH NODE, EXCISION

Block	Sect. Site	PCs
2	u	2

Source: NCI Genomic Data Commons file c922889b-fb69-44a2-98a2-7eb39c82f8b3 (TCGA-BQ-7051.B7CA23EF-A832-423B-8B91-06F24E906223.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).